MMRF case MMRF_1857 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a56024d4-beda-4739-9595-278a3e60a191

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.3 years (26,054 days); ISS stage: II; Days to last known disease status: 1,069 days (2.9 years); Days to last follow up: 1,069 days (2.9 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 114 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 114 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 124 days; Days to treatment end: 219 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 124 days; Days to treatment end: 206 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 250 days; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 377 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 101 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 19.5 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 0.208 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 6.74 ×10⁹/L; Absolute Neutrophil 4.84 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.08 mmol/L; Albumin 29 g/L; Total Protein 6.5 g/dL; Glucose 7.43 mmol/L.
- Day 79 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 91.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.49 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.
- Day 188 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 49.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.95 mg/dL; Beta 2 Microglobulin 0.21 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 7.48 mmol/L.
- Day 273 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Beta 2 Microglobulin 0.21 µg/mL; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.45 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 5.61 mmol/L.
- Day 334 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Hemoglobin 7.75 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 7.48 mmol/L.
- Day 446 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Hemoglobin 7.44 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.68 mmol/L.
- Day 532 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 41.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 5.17 mmol/L.
- Day 614 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Hemoglobin 6.76 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.28 mmol/L.
- Day 1,010: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.
- Day 1,069: Serum Free Immunoglobulin Light Chain, Kappa 10.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day -5: Weight: 57 kg; Height: 157 cm.

Biospecimens (2 samples)
- Sample MMRF_1857_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1857_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
